Somatic mutation profile of tumor specimen 0DVM1J from CCDI case PBCNAS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.8 years (7,238 days).
Specimen 0DVM1J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7be8a597-460d-439f-8b00-5cc659ef2988.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVM1V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5079ecfa-0ef4-4bf3-a287-db94bb95c360

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 4, Silent 4, Frame Shift Ins 2, 5'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 141/432 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.13126G>A p.G4376S | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.66); catalogued as rs757616938; called by muse, mutect2, varscan2
- DDX3X | c.1066T>G p.F356V (on ENST00000399959; = p.F357V on NM_001356.5) | Missense Mutation (SNP) | VAF 136/289 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67863677, COSV67864841; called by muse, mutect2, varscan2
- DLGAP1 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 137/380 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as rs748351626, COSV59792055; called by muse, mutect2
- EGFLAM | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 194/399 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs1242594013; called by muse, mutect2, varscan2
- GUSB | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 196/442 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs747572640, CM960798, COSV59221525; called by muse, mutect2, varscan2
- IL17REL | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs774797196; called by muse, mutect2, varscan2
- KRT82 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs772080389; called by muse, mutect2, varscan2
- NEFM | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 202/437 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); catalogued as rs757795369, COSV99647002; called by muse, mutect2, varscan2
- PRSS45P | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 112/283 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as rs190009780; called by muse, mutect2, varscan2
- PTK2 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 107/255 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs775267050; called by muse, mutect2, varscan2
- WAC | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 121/293 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.342); catalogued as COSV100610837, COSV100611167; called by muse, mutect2, varscan2
- WDR87 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 146/337 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs762441385, COSV58203927; called by muse, mutect2, varscan2
- XYLT2 | c.1820C>T p.T607M | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs138319215; called by muse, mutect2, varscan2
- COL1A2 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPF1 | c.268_271+1dup p.X90_splice | Splice Site (INS) | VAF 116/260 reads (45%) | called by mutect2, varscan2
- GSE1 | c.1313_1316dup p.L440Efs*41 | Frame Shift Ins (INS) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- OSBPL5 | c.1642A>G p.T548A | Missense Mutation (SNP) | VAF 160/377 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PCDHGB1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 178/407 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PTCH1 | c.1340_1343del p.L447Sfs*8 | Frame Shift Del (DEL) | VAF 137/155 reads (88%) | called by pindel, varscan2
- RNF5 | c.526dup p.W176Lfs*27 | Frame Shift Ins (INS) | VAF 144/366 reads (39%) | called by mutect2, varscan2
- SLC22A8 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD15 | c.714G>A p.S238= | Silent (SNP) | VAF 101/226 reads (45%) | catalogued as rs772192321; called by muse, mutect2, varscan2
- CHTF18 | c.876G>A p.T292= | Silent (SNP) | VAF 65/156 reads (42%) | catalogued as rs371334131; called by muse, mutect2, varscan2
- LAS1L | c.747C>T p.S249= | Silent (SNP) | VAF 180/402 reads (45%) | catalogued as rs745356580, COSV56707814; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF81 | c.1743T>A p.P581= | Silent (SNP) | VAF 122/267 reads (46%) | catalogued as COSV58576509; called by muse, mutect2, varscan2
- CCDC14 | c.230+51T>C | Intron (SNP) | VAF 12/324 reads (4%) | called by muse, mutect2
- FOXH1 | c.-18C>T | 5'UTR (SNP) | VAF 87/168 reads (52%) | catalogued as rs1395821235; called by muse, mutect2, varscan2
- MEST | c.262-15G>A | Intron (SNP) | VAF 57/114 reads (50%) | catalogued as rs375680311; called by muse, mutect2, varscan2
- PSMD14 | c.48+57G>A | Intron (SNP) | VAF 40/67 reads (60%) | called by muse, mutect2, varscan2
- RIMS2 | c.177-44400A>T | Intron (SNP) | VAF 104/301 reads (35%) | called by muse, mutect2, varscan2
